Somatic mutation profile of tumor specimen TCGA-EM-A3SU-06A (aliquot TCGA-EM-A3SU-06A-11D-A22Z-08) from TCGA case TCGA-EM-A3SU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.2 years (15,768 days).
Specimen TCGA-EM-A3SU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dcd216b-6d41-4e82-90c9-c6a0196e3eb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3SU-10A (Blood Derived Normal), aliquot TCGA-EM-A3SU-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62452407-9a88-4343-a521-e710cc994de0

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- FAM189A2 | c.124-2A>C p.X42_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99975038; called by muse, varscan2
- KLF7 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs536720710, COSV100519156; called by mutect2, varscan2
- MAGEC1 | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752999850, COSV53571509, COSV53574727; called by muse, mutect2
- REG1A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1401496725, COSV52068880, COSV52071650; called by muse, mutect2, varscan2
- SEMA4C | c.551dup p.L185Pfs*10 | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
